Gene-level copy-number profile of tumor specimen TCGA-FR-A729-06A from TCGA case TCGA-FR-A729, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.4 years (20,229 days).
Specimen TCGA-FR-A729-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.f85e27a6-58cd-4740-af8c-e71b14c4719b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A729-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6450c181-aeb9-4682-9dda-4475c3475a16

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 2; copy number 2: 9,313; copy number 3: 22,240; copy number 4: 14,430; copy number 5: 4,576; copy number 6: 6,750; copy number 7: 2,480; copy number 8: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A729-06A-11D-A34T-01): tumor purity 0.44, ploidy 3.52, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:66,946,116–67,899,619, 8 genes (within-gene range 0–2): RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3.
- chr18:67,672,221–67,767,051, 1 gene (within-gene range 0–1): AC022655.1.
- chr18:67,788,268–67,814,822, 2 genes: AC114689.1, LINC01903.
- chr19:38,647,649–38,731,589, 2 genes: ACTN4, AC008649.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,494 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,142,850–22,921,500, 15 genes, copy number 7 (within-gene range 3–7): AL445253.1, MIR4418, PPIAP34, AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253.
- chr2:100,271,875–100,676,038, 13 genes, copy number 8 (within-gene range 6–8): LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868.
- chr7:3,301,252–8,094,272, 114 genes, copy number 7 (broad region; genes not listed).
- chr7:8,114,025–8,116,561, 1 gene, copy number 7: AC006042.1.
- chr7:10,901,978–23,897,335, 165 genes, copy number 7 (broad region; genes not listed).
- chr11:25,140,533–25,141,023, 1 gene, copy number 8: AC087373.1.
- chr14:105,209,286–105,315,589, 1 gene, copy number 7 (within-gene range 4–7): BRF1.
- chr14:105,300,563–106,875,071, 211 genes, copy number 7 (broad region; genes not listed).
- chr15:61,298,791–61,635,449, 2 genes, copy number 7 (within-gene range 4–7): AC104574.2, AC104574.1.
- chr16:53,544,339–55,008,306, 25 genes, copy number 7: AC007497.2, RPGRIP1L, AC007497.1, FTO, AC007496.2, AC007496.3, AC007496.1, AC007347.1, AC007347.2, AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, AC007343.1, LINC02183, AC007491.1, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34.
- chr16:55,352,721–68,722,616, 337 genes, copy number 7 (broad region; genes not listed).
- chr16:68,742,480–68,742,588, 1 gene, copy number 7: RNA5SP429.
- chr16:75,119,558–77,105,297, 53 genes, copy number 7 (within-gene range 4–7): AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL, AC105430.1, RNA5SP430, AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).
- chr21:10,328,411–16,719,157, 97 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
